Somatic mutation profile of tumor specimen TCGA-NH-A8F7-01A (aliquot TCGA-NH-A8F7-01A-11D-A40P-10) from TCGA case TCGA-NH-A8F7, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 53.5 years (19,535 days).
Specimen TCGA-NH-A8F7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c01bed6-01df-4db3-aad0-44f609a9f47d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NH-A8F7-10A (Blood Derived Normal), aliquot TCGA-NH-A8F7-10A-01D-A40P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61b9f7b4-a00d-4176-82db-b51c975577f8

The open-access MAF lists 136 somatic variants for this specimen: 104 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 30, Nonsense Mutation 7, Splice Site 4, Frame Shift Del 2, In Frame Del 2, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4033G>T p.E1345* | Nonsense Mutation (SNP) | VAF 38/124 reads (31%) | catalogued as rs1211642532, CM994565, COSV57322919; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.12298G>A p.V4100I | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs758785338, COSV63665946; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856_861del p.E286_E287del | In Frame Del (DEL) | VAF 32/42 reads (76%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTSL4 | c.2009G>C p.R670P | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99646739; called by muse, mutect2, varscan2
- AGRN | c.1118C>T p.S373L | Missense Mutation (SNP) | VAF 69/232 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as rs747332721, COSV101038587; called by muse, mutect2, varscan2
- AKNA | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs578095975, COSV56314528; called by muse, mutect2, varscan2
- ALMS1 | c.5668A>T p.I1890L | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.406); catalogued as COSV100041147; called by muse, mutect2, varscan2
- ANKRD11 | c.7154G>A p.R2385H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99968123; called by muse, mutect2, varscan2
- APC | c.2306T>A p.L769* | Nonsense Mutation (SNP) | VAF 37/67 reads (55%) | catalogued as COSV99965279; called by muse, mutect2, varscan2
- AR | c.1444G>A p.G482S | Missense Mutation (SNP) | VAF 32/438 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (1); catalogued as COSV65953108; called by muse, mutect2
- ARID4A | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100794005; called by muse, mutect2, varscan2
- BARD1 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV99637877; called by muse, mutect2, varscan2
- BRWD3 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 138/675 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV64749640; called by muse, mutect2, varscan2
- CADM4 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55930200; called by muse, mutect2, varscan2
- CCDC141 | c.1760C>A p.T587N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as COSV55368943; called by muse, mutect2, varscan2
- CCDC158 | c.2148G>T p.K716N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1178202182, COSV101187156; called by muse, mutect2, varscan2
- CCDC85A | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV101339378; called by muse, mutect2, varscan2
- CNOT1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV57764597; called by muse, mutect2, varscan2
- COL22A1 | c.4231G>C p.G1411R | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100276373; called by muse, mutect2, varscan2
- COL3A1 | c.3045C>A p.N1015K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100482469; called by muse, mutect2, varscan2
- COL4A6 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 69/94 reads (73%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV100563363; called by muse, mutect2, varscan2
- DCAF8L1 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 34/333 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV101491386; called by muse, mutect2
- DISP3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770662011, COSV53824966; called by muse, mutect2
- DLGAP2 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.988); catalogued as rs765947691, COSV101421035; called by muse, mutect2, varscan2
- DSCAM | c.4423C>A p.P1475T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101259138; called by muse, mutect2
- EEF1A2 | c.569T>C p.F190S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.287); catalogued as COSV99419024; called by muse, mutect2, varscan2
- EIF3D | c.446A>T p.K149I | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.793); catalogued as COSV99341347; called by muse, mutect2, varscan2
- EIF4B | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs747657993, COSV50401616; called by muse, mutect2, varscan2
- ERF | c.233A>G p.Y78C | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99724491; called by muse, mutect2, varscan2
- FAM234A | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs200473849; called by muse, mutect2, varscan2
- FAT3 | c.8662A>G p.T2888A | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV53076152; called by muse, mutect2
- FBN2 | c.666C>G p.N222K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52493112; called by muse, mutect2, varscan2
- FGF10 | c.107C>G p.T36S | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.066); catalogued as COSV99240090; called by muse, mutect2, varscan2
- FRMD4B | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as COSV101273331; called by muse, mutect2, varscan2
- FZR1 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100553391; called by muse, mutect2, varscan2
- GNB4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.856); catalogued as rs955229785, COSV99224037; ClinVar: uncertain significance; called by muse, mutect2
- GRM4 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1186933275, COSV65219072; called by muse, mutect2, varscan2
- HRG | c.698G>T p.S233I | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV104372055, COSV99214582; called by muse, mutect2, varscan2
- ITGA9 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs199626430, COSV53250416; called by muse, mutect2, varscan2
- KCNT2 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 43/152 reads (28%) | catalogued as COSV99651573; called by muse, mutect2, varscan2
- KIAA1755 | c.2326C>T p.P776S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99641473; called by muse, mutect2, varscan2
- LAMA1 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV101055027; called by muse, mutect2, varscan2
- LCK | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV60738336; called by muse, mutect2, varscan2
- LMBR1L | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs528446706, COSV99918507; called by muse, mutect2, varscan2
- LNX1 | c.1795G>A p.E599K (on ENST00000263925 / NM_001126328.3; = p.E503K on NM_032622.2) | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as COSV99819448; called by muse, mutect2
- LRRC37A2 | c.2926C>G p.L976V | Missense Mutation (SNP) | VAF 96/782 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs573399914, COSV61002201; called by muse, mutect2, varscan2
- MAGT1 | c.698G>A p.G233D (on ENST00000618282 / NM_001367916.1; = p.G265D on NM_032121.5) | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100800047; called by muse, mutect2, varscan2
- MAST3 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs1220688900, COSV99444416; called by muse, mutect2, varscan2
- MFSD14A | c.244-1G>A p.X82_splice | Splice Site (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100924599; called by muse, mutect2, varscan2
- MTUS2 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs372355162; called by muse, mutect2, varscan2
- NAALADL2 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as COSV101435739, COSV70794384; called by muse, mutect2
- NCKAP5L | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100258335; called by muse, mutect2, varscan2
- NLGN4X | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 139/231 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1569195407, COSV52011605; called by muse, mutect2, varscan2
- NPR1 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs770463801, COSV100901960; called by muse, mutect2, varscan2
- NRK | c.3397G>T p.D1133Y | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99686588; called by muse, mutect2, varscan2
- OCRL | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100843338; called by muse, mutect2, varscan2
- ODF3L1 | c.13A>C p.K5Q | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100150686; called by muse, mutect2, varscan2
- OR2A7 | c.647C>A p.S216* | Nonsense Mutation (SNP) | VAF 64/668 reads (10%) | catalogued as COSV101512179, COSV71828541; called by muse, mutect2
- OR5D18 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs201872777, COSV100450902, COSV61737031; called by muse, mutect2, varscan2
- OTOGL | c.2365G>T p.D789Y (on ENST00000547103; = p.D780Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV101509019; called by muse, mutect2
- PAX7 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 54/101 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371475871; called by muse, mutect2, varscan2
- PCDH15 | c.5041G>A p.G1681S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated, low confidence (0.45); catalogued as COSV100903510, COSV64673200; called by muse, mutect2, varscan2
- PCDHB7 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99175668; called by muse, mutect2, varscan2
- PCDHGA6 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs781173070, COSV99530784; called by muse, mutect2, varscan2
- PCDHGB7 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.222); catalogued as COSV99530788; called by muse, mutect2, varscan2
- PCSK5 | c.4592A>C p.H1531P | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV101377252; called by muse, mutect2, varscan2
- PFKP | c.2264G>A p.R755Q | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs141623019; called by muse, mutect2, varscan2
- PHF10 | c.325+2T>G p.X109_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as rs1190636078, COSV100199755; called by muse, mutect2, varscan2
- PIAS1 | c.1247T>G p.M416R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99986514; called by muse, mutect2, varscan2
- PIK3C2G | c.3465G>T p.L1155F (on ENST00000676171; = p.L1114F on NM_004570.5) | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56811967, COSV99849572; called by muse, mutect2, varscan2
- PITPNM1 | c.3154G>A p.V1052I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1457648242, COSV99653539; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as COSV100982345; called by muse, mutect2, varscan2
- PPP1R12C | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 80/169 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765264618, COSV99669978; called by muse, mutect2, varscan2
- PREX2 | c.3828T>A p.C1276* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | catalogued as COSV99905118, COSV99911070; called by muse, mutect2, varscan2
- RC3H2 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | catalogued as COSV100106293; called by muse, mutect2, varscan2
- RFX2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV100353535; called by muse, mutect2, varscan2
- RNASEL | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs766296817, COSV100842539; called by muse, mutect2, varscan2
- ROCK1 | c.3772G>T p.A1258S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101296240; called by muse, mutect2, varscan2
- SENP6 | c.2288+1G>A p.X763_splice | Splice Site (SNP) | VAF 199/371 reads (54%) | catalogued as COSV64185424; called by muse, mutect2, varscan2
- SGCD | c.380G>T p.G127V (on ENST00000435422 / NM_001128209.2; = p.G128V on NM_000337.5) | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100548728; called by muse, mutect2, varscan2
- SH3RF3 | c.1576G>T p.V526L | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV58697947; called by muse, mutect2, varscan2
- SLC26A9 | c.1501A>G p.N501D | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61600825; called by muse, mutect2, varscan2
- SLC29A4 | c.1042G>A p.V348M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs370235014; called by muse, mutect2, varscan2
- SLC35A2 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs782219505, COSV99504048; called by muse, mutect2
- SLC8A2 | c.1214G>A p.C405Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99369653; called by muse, mutect2, varscan2
- SPAG16 | c.1791C>A p.H597Q | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.417); catalogued as COSV56970411; called by muse, mutect2, varscan2
- SSBP2 | c.282C>T p.Y94= | Splice Region (SNP) | VAF 32/62 reads (52%) | catalogued as rs201909212, COSV57792532; called by muse, mutect2, varscan2
- TDRKH | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100917874; called by muse, mutect2, varscan2
- THSD7A | c.3531T>G p.C1177W | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101439720; called by mutect2, varscan2
- TUT4 | c.2785C>G p.P929A | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV99931794; called by muse, mutect2, varscan2
- UBR3 | c.3800G>A p.R1267H | Missense Mutation (SNP) | VAF 66/110 reads (60%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs367980134; called by muse, mutect2, varscan2
- UNC13C | c.2629G>C p.D877H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.018); catalogued as COSV52843929, COSV52933243, COSV99036561; called by muse, mutect2
- USP29 | c.540T>G p.N180K | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV99517641; called by muse, mutect2, varscan2
- VCAN | c.10012C>T p.R3338W | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54112041; called by muse, mutect2, varscan2
- WWC3 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs370430485, COSV101081044; called by muse, mutect2, varscan2
- YME1L1 | c.571A>C p.S191R (on ENST00000326799 / NM_139312.3; = p.S134R on NM_014263.4) | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100463248; called by muse, mutect2, varscan2
- ZMYM2 | c.3318A>C p.L1106F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.424); catalogued as COSV101243524; called by muse, mutect2, varscan2
- ZNF418 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs1351080196, COSV101268889; called by muse, mutect2, varscan2
- ITGAL | c.2786+2dup p.X929_splice | Splice Site (INS) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- PCDHGA12 | c.1079_1098del p.S360Cfs*7 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- PDZD2 | c.7884del p.E2629Kfs*37 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- PSMA7 | c.142_144del p.K48del | In Frame Del (DEL) | VAF 22/115 reads (19%) | called by pindel, varscan2
- PTPRO | c.498G>T p.M166I | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); called by muse, mutect2
- ZNF658 | c.2156G>T p.C719F | Missense Mutation (SNP) | VAF 132/451 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- ADGRD1 | c.2133C>T p.G711= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as rs1566127364, COSV99893975; called by muse, mutect2, varscan2
- AFAP1L2 | c.1470C>A p.I490= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV100412165; called by muse, mutect2, varscan2
- AHNAK2 | c.2850G>A p.A950= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as rs779221842, COSV60907959; called by muse, mutect2, varscan2
- ARHGAP27 | c.2094G>A p.A698= (on ENST00000428638 / NM_001282290.1; = p.A357= on NM_199282.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1331889610, COSV100976448; called by muse, mutect2, varscan2
- ATP11A | c.1545C>T p.V515= | Silent (SNP) | VAF 25/119 reads (21%) | catalogued as rs1040466378, COSV52106200; called by muse, mutect2, varscan2
- CCDC110 | c.2247C>T p.Y749= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as rs752180798, COSV56873532; called by muse, mutect2, varscan2
- CCDC171 | c.3324C>G p.L1108= | Silent (SNP) | VAF 98/232 reads (42%) | catalogued as COSV52634128; called by muse, mutect2, varscan2
- CCDC88B | c.1638G>A p.E546= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs1005413850, COSV100105014; called by muse, mutect2, varscan2
- CMTM4 | c.459C>T p.A153= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs144160189; called by muse, mutect2, varscan2
- COL8A1 | c.1923C>T p.N641= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as rs773581749, COSV53729554; called by muse, mutect2, varscan2
- CSTF2 | c.63G>A p.G21= | Silent (SNP) | VAF 34/183 reads (19%) | catalogued as COSV63376100; called by muse, mutect2, varscan2
- DSCAML1 | c.3738C>A p.T1246= (on ENST00000321322; = p.T1186= on NM_020693.4) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100354593; called by muse, mutect2, varscan2
- DSCAML1 | c.342C>T p.S114= (on ENST00000321322; = p.S54= on NM_020693.4) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs373723950; called by muse, mutect2, varscan2
- FLII | c.810C>T p.H270= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs755230101, COSV100493465; called by muse, varscan2
- FOXK1 | c.1677C>T p.D559= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100194584; called by muse, mutect2, varscan2
- HMOX2 | c.741G>A p.E247= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99566345; called by muse, mutect2, varscan2
- JPH2 | c.555C>T p.S185= | Silent (SNP) | VAF 27/417 reads (6%) | catalogued as COSV65901801; called by muse, mutect2
- KDM4B | c.2220G>A p.T740= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs768283280, COSV50208944; called by muse, mutect2, varscan2
- MYH8 | c.3468C>T p.A1156= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs1308206260, COSV67964754; called by muse, mutect2, varscan2
- NLRP11 | c.2472G>A p.T824= | Silent (SNP) | VAF 55/122 reads (45%) | catalogued as rs370425219, COSV100789633; called by muse, mutect2, varscan2
- NPAP1 | c.747C>A p.A249= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100274789; called by muse, mutect2, varscan2
- NPY2R | c.555C>A p.I185= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs751901202, COSV61527640; called by muse, mutect2, varscan2
- RIMBP2 | c.222C>T p.S74= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs753685683, COSV99898353; called by muse, mutect2, varscan2
- RNF17 | c.2784T>C p.P928= | Silent (SNP) | VAF 59/189 reads (31%) | catalogued as COSV99692216; called by muse, mutect2, varscan2
- RPS6KA3 | c.435T>C p.L145= | Silent (SNP) | VAF 230/1012 reads (23%) | catalogued as COSV101084135; called by muse, mutect2, varscan2
- SLC4A1 | c.1368T>C p.A456= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99292996; called by muse, mutect2, varscan2
- SLC6A16 | c.1791C>T p.D597= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV100242570; called by muse, mutect2, varscan2
- SLITRK5 | c.1353C>T p.R451= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs772460649, COSV61521812; called by muse, mutect2, varscan2
- SRA1 | c.375C>T p.C125= | Silent (SNP) | VAF 44/97 reads (45%) | catalogued as COSV99782079; called by muse, mutect2, varscan2
- TPRG1L | c.171C>T p.R57= | Silent (SNP) | VAF 11/16 reads (69%) | catalogued as rs970861576, COSV60723636; called by muse, mutect2, varscan2
- DENND10P1 | n.753C>T | RNA (SNP) | VAF 34/501 reads (7%) | called by muse, mutect2
- TTN | c.34265-5693C>T | Intron (SNP) | VAF 27/241 reads (11%) | catalogued as rs1384922524, COSV59890302; called by muse, mutect2, varscan2
